Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A86X, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A86X-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localization: L frontal

Diagnosis: Oligodendroglioma (grade II WHO)

Name of Pathologist:

ICD-O-3

Oligodendroglioma, grade II
9450/3

Site:
Brain, supratentorial NOS
C71.0

Brain, frontal lobe
C71.1
10/20/13

IP/AA Discrepancy		✓

Source: NCI Genomic Data Commons file 19fa04a7-c1f7-4163-9bfc-a5becc08297d (TCGA-QH-A86X.CC0201F5-5747-4A46-A364-8EC6F16D67C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).